Somatic mutation profile of tumor specimen HCM-CSHL-1262-C19-06A (aliquot HCM-CSHL-1262-C19-06A-11D-A882-36) from HCMI case HCM-CSHL-1262-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 65.4 years (23,884 days).
Specimen HCM-CSHL-1262-C19-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6fa59d04-fad5-44a6-a966-111f70abb240.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-1262-C19-11A (Solid Tissue Normal), aliquot HCM-CSHL-1262-C19-11A-01D-A882-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/276e44b8-34b6-47f1-af36-a3cfbfb04edd

The open-access MAF lists 177 somatic variants for this specimen: 121 protein-altering or splice-affecting, 46 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 112, Silent 46, Nonsense Mutation 4, Frame Shift Ins 3, Intron 3, 5'Flank 2, RNA 2, 3'UTR 2, Frame Shift Del 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS17 | c.1721+1G>A p.X574_splice | Splice Site (SNP) | VAF 157/199 reads (79%) | catalogued as rs749116256, CS097863; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DUSP16 | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 150/314 reads (48%) | hotspot (GDC flag); catalogued as COSV53806110; called by muse, varscan2
- PIK3CA | c.3203dup p.N1068Kfs*5 | Frame Shift Ins (INS) | VAF 62/315 reads (20%) | catalogued as rs587776802; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.482C>A p.A161D | Missense Mutation (SNP) | VAF 147/506 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1064795691, COSV52678014, COSV52747111, COSV52839912, COSV53772942; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA13 | c.10802A>G p.E3601G | Missense Mutation (SNP) | VAF 21/288 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1218974230; called by muse, mutect2
- ADCY7 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 109/495 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs201627898, COSV54270739; called by muse, mutect2, varscan2
- AFF3 | c.2923C>T p.R975C | Missense Mutation (SNP) | VAF 46/323 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as rs868486028, COSV57866119; called by muse, mutect2, varscan2
- APC | c.3493A>T p.K1165* | Nonsense Mutation (SNP) | VAF 110/216 reads (51%) | catalogued as COSV57326930, COSV57341138; called by muse, mutect2, varscan2
- ASIC4 | c.1109T>A p.I370N (on ENST00000347842 / NM_182847.3; = p.I389N on NM_018674.6) | Missense Mutation (SNP) | VAF 218/420 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99705223; called by muse, varscan2
- CCDC186 | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.71); catalogued as COSV100991112; called by muse, mutect2, varscan2
- COLGALT2 | c.1756G>A p.D586N | Missense Mutation (SNP) | VAF 340/528 reads (64%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs534486400; called by muse, mutect2, varscan2
- CTNNA2 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 68/163 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs369970894; called by muse, varscan2
- CTSL | c.896A>T p.K299M | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58246737; called by muse, mutect2, varscan2
- DNAH1 | c.2255G>A p.R752Q | Missense Mutation (SNP) | VAF 94/531 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs749446487, COSV70230279; called by muse, mutect2, varscan2
- DOCK8 | c.3868G>A p.A1290T | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as rs932409929; called by muse, mutect2, varscan2
- DVL1 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 297/441 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs767735434, COSV100229339; called by muse, mutect2, varscan2
- ERN2 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 31/416 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99890600; called by muse, mutect2
- ETAA1 | c.1245A>T p.E415D | Missense Mutation (SNP) | VAF 114/331 reads (34%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs759198673; called by muse, mutect2, varscan2
- FGD5 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 159/614 reads (26%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs113314322; called by muse, mutect2, varscan2
- FYB1 | c.1963G>A p.D655N (on ENST00000351578 / NM_199335.5; = p.D701N on NM_001465.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 114/239 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as rs932786216; called by muse, mutect2, varscan2
- FYB1 | c.1754C>T p.S585L | Missense Mutation (SNP) | VAF 79/345 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100685897; called by muse, mutect2, varscan2
- GPM6A | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 59/203 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.122); catalogued as COSV99703150; called by muse, mutect2, varscan2
- GTF2IRD2B | c.2446G>A p.E816K | Missense Mutation (SNP) | VAF 94/602 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.187); catalogued as COSV100441254; called by muse, mutect2, varscan2
- HELZ2 | c.3208G>A p.A1070T (on ENST00000467148 / NM_001037335.2; = p.A501T on NM_033405.3) | Missense Mutation (SNP) | VAF 277/846 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV100915440; called by muse, mutect2, varscan2
- IGLON5 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 123/425 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs746860483; called by muse, mutect2, varscan2
- IWS1 | c.2251C>T p.R751C | Missense Mutation (SNP) | VAF 125/277 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99767384; called by muse, mutect2, varscan2
- KL | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 154/814 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs1482126606, COSV101199060; called by muse, mutect2, varscan2
- LAMA3 | c.7121G>A p.R2374Q (on ENST00000313654 / NM_198129.4; = p.R765Q on NM_000227.6) | Missense Mutation (SNP) | VAF 179/239 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs563440658, COSV52541866; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LHX4 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 301/469 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374435549; called by muse, mutect2, varscan2
- LILRA2 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 286/560 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs764683666, COSV99253321; called by muse, varscan2
- LYRM4 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 14/294 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV57993888; called by muse, mutect2
- MFSD4A | c.373G>C p.V125L | Missense Mutation (SNP) | VAF 387/562 reads (69%) | SIFT tolerated (0.24); PolyPhen benign (0.083); catalogued as COSV65656688; called by muse, varscan2
- MSH2 | c.192C>G p.I64M | Missense Mutation (SNP) | VAF 52/451 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.661); catalogued as rs1395172053; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTA3 | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 26/255 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100608740; called by muse, mutect2
- OR2T6 | c.824C>G p.S275C | Missense Mutation (SNP) | VAF 128/415 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100861474; called by muse, mutect2, varscan2
- PCDH11X | c.2473G>A p.V825I | Missense Mutation (SNP) | VAF 246/290 reads (85%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs377250651, COSV53454579; called by muse, mutect2, varscan2
- PCDHA10 | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 332/619 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.135); catalogued as rs375062704, COSV56527999; called by muse, mutect2, varscan2
- PDZD2 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 100/177 reads (56%) | SIFT tolerated (0.74); PolyPhen benign (0.052); catalogued as rs368237088; called by muse, mutect2, varscan2
- PLEK | c.218C>T p.T73M | Missense Mutation (SNP) | VAF 89/276 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.68); catalogued as rs200352669, COSV52250616, COSV52252675; called by muse, mutect2, varscan2
- PPP4R3C | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 164/186 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1305786854; called by muse, mutect2, varscan2
- PRAMEF8 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 58/796 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1278321334; called by muse, mutect2
- RFWD3 | c.2131G>A p.D711N | Missense Mutation (SNP) | VAF 144/402 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs1445145229; called by muse, mutect2, varscan2
- RYR1 | c.7105C>T p.R2369W | Missense Mutation (SNP) | VAF 320/657 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV62096336; called by muse, mutect2, varscan2
- SCRG1 | c.106C>G p.H36D | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.29); catalogued as COSV56636186; called by muse, mutect2, varscan2
- SIX6 | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 165/393 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1344962002, COSV59803126; called by muse, mutect2, varscan2
- TMEM132D | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 228/490 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs756539559, COSV70601435, COSV70624212; called by muse, mutect2, varscan2
- TMEM150C | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 126/322 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs201010480, COSV71389101; called by muse, mutect2, varscan2
- TMEM245 | c.931G>A p.G311R | Missense Mutation (SNP) | VAF 34/245 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.17); catalogued as COSV65824255; called by muse, mutect2, varscan2
- TSSK1B | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 153/488 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs374009361; called by muse, mutect2, varscan2
- TTN | c.24116G>A p.R8039H (on ENST00000591111; = p.R7112H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/106 reads (45%) | PolyPhen probably damaging (0.99); catalogued as rs376290076, COSV100624013; called by muse, mutect2, varscan2
- TUBA3C | c.260T>A p.F87Y | Missense Mutation (SNP) | VAF 133/423 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.115); catalogued as rs1204807947; called by muse, mutect2, varscan2
- ZNF521 | c.2506G>A p.E836K | Missense Mutation (SNP) | VAF 108/278 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.205); catalogued as rs138180600; called by muse, mutect2, varscan2
- A2ML1 | c.3147G>C p.Q1049H | Missense Mutation (SNP) | VAF 32/368 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2
- ADGRV1 | c.5383A>C p.N1795H | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK2 | c.1480G>T p.A494S | Missense Mutation (SNP) | VAF 88/182 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- ARID1A | c.5655_5657delinsGG p.E1886Gfs*37 | Frame Shift Del (DEL) | VAF 131/550 reads (24%) | called by pindel, varscan2*
- ARL6IP4 | c.500A>T p.E167V | Missense Mutation (SNP) | VAF 15/538 reads (3%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); called by muse, mutect2
- ARL9 | c.665C>T p.A222V (on ENST00000640821 / NM_001363794.2; = p.A80V on NM_206919.2) | Missense Mutation (SNP) | VAF 63/237 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- CARMIL1 | c.2543G>C p.R848T | Missense Mutation (SNP) | VAF 39/335 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC83 | c.521A>G p.K174R | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT tolerated (0.96); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CFAP47 | c.2177C>A p.S726* | Nonsense Mutation (SNP) | VAF 69/186 reads (37%) | called by muse, mutect2, varscan2
- CIBAR1 | c.628C>G p.Q210E | Missense Mutation (SNP) | VAF 20/454 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.028); called by muse, mutect2
- CLEC20A | c.378G>T p.K126N | Missense Mutation (SNP) | VAF 189/290 reads (65%) | SIFT tolerated (0.09); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- CNTN5 | c.427G>C p.D143H | Missense Mutation (SNP) | VAF 39/227 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- COL16A1 | c.1199A>T p.Q400L | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- CPXCR1 | c.520A>C p.K174Q | Missense Mutation (SNP) | VAF 68/303 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DDX5 | c.216G>C p.E72D | Missense Mutation (SNP) | VAF 53/247 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DEFB125 | c.316A>C p.K106Q | Missense Mutation (SNP) | VAF 113/684 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- DMRTA2 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 49/262 reads (19%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.772); called by muse, varscan2
- DOCK7 | c.3228C>G p.F1076L (on ENST00000635253 / NM_001367561.1; = p.F1045L on NM_033407.3) | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- DYNC1LI2 | c.800C>G p.A267G | Missense Mutation (SNP) | VAF 29/234 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- DYRK2 | c.767A>T p.E256V (on ENST00000344096 / NM_006482.3; = p.E183V on NM_003583.4) | Missense Mutation (SNP) | VAF 52/338 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EPHB4 | c.1973G>A p.R658Q | Missense Mutation (SNP) | VAF 227/542 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- EXOC3L1 | c.2055G>T p.L685F | Missense Mutation (SNP) | VAF 188/526 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GATC | c.13T>G p.L5V | Missense Mutation (SNP) | VAF 80/280 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0); called by mutect2, varscan2
- GCNT7 | c.786C>G p.F262L | Missense Mutation (SNP) | VAF 100/668 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HIPK1 | c.3512C>T p.A1171V (on ENST00000369558 / NM_001369806.1; = p.A777V on NM_181358.2) | Missense Mutation (SNP) | VAF 44/308 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- HMGCR | c.2051G>C p.S684T | Missense Mutation (SNP) | VAF 30/280 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- IL12RB1 | c.1661G>T p.G554V | Missense Mutation (SNP) | VAF 140/277 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JMJD4 | c.710A>G p.D237G | Missense Mutation (SNP) | VAF 72/738 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KMT2A | c.9157A>C p.S3053R | Missense Mutation (SNP) | VAF 236/499 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KRT3 | c.1441C>A p.L481M | Missense Mutation (SNP) | VAF 43/364 reads (12%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- MAGEB3 | c.242A>T p.K81M | Missense Mutation (SNP) | VAF 39/274 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- MAN2A2 | c.1006T>C p.W336R | Missense Mutation (SNP) | VAF 133/177 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MARCKS | c.665dup p.A223Gfs*119 | Frame Shift Ins (INS) | VAF 190/568 reads (33%) | called by mutect2, varscan2
- MICU1 | c.530A>C p.D177A | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2
- MIPOL1 | c.985T>C p.Y329H | Missense Mutation (SNP) | VAF 30/390 reads (8%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.906); called by muse, mutect2
- MSC | c.569C>G p.S190C | Missense Mutation (SNP) | VAF 39/552 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2
- NIBAN1 | c.816G>A p.W272* | Nonsense Mutation (SNP) | VAF 48/239 reads (20%) | called by muse, mutect2, varscan2
- NME8 | c.1113T>A p.F371L | Missense Mutation (SNP) | VAF 44/240 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- NXNL1 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- OR51A4 | c.839T>C p.V280A | Missense Mutation (SNP) | VAF 108/297 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PDCD11 | c.3506A>G p.E1169G | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- PDHA2 | c.82T>A p.S28T | Missense Mutation (SNP) | VAF 100/246 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PDYN | c.38T>C p.L13P | Missense Mutation (SNP) | VAF 28/579 reads (5%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.497); called by muse, mutect2
- PHLDB2 | c.3407G>T p.C1136F (on ENST00000393925 / NM_001134439.2; = p.C1093F on NM_145753.2) | Missense Mutation (SNP) | VAF 35/491 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- PNPLA7 | c.2966G>T p.G989V | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- PPIAL4G | c.53G>C p.G18A | Missense Mutation (SNP) | VAF 68/640 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- PPRC1 | c.1822G>C p.D608H | Missense Mutation (SNP) | VAF 121/432 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); called by muse, varscan2
- RELN | c.7858C>T p.P2620S | Missense Mutation (SNP) | VAF 78/303 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- RFTN1 | c.1534G>C p.V512L | Missense Mutation (SNP) | VAF 87/462 reads (19%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- RGS13 | c.26G>T p.C9F | Missense Mutation (SNP) | VAF 90/406 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.273); called by mutect2, varscan2
- RNF213 | c.14819A>T p.Q4940L | Missense Mutation (SNP) | VAF 65/496 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- RPL15 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 40/402 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SEC24C | c.2123C>T p.T708I | Missense Mutation (SNP) | VAF 168/617 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SGMS2 | c.610C>G p.L204V | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.696); called by muse, varscan2
- SH3PXD2A | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 39/347 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SLC22A1 | c.455A>C p.Q152P | Missense Mutation (SNP) | VAF 246/464 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2
- SLC52A1 | c.1308T>G p.F436L | Missense Mutation (SNP) | VAF 94/329 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SLC8A1 | c.2783G>A p.R928Q | Missense Mutation (SNP) | VAF 119/443 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPATA31E1 | c.2744C>A p.T915N | Missense Mutation (SNP) | VAF 223/341 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- SSC5D | c.4237C>G p.P1413A | Missense Mutation (SNP) | VAF 57/524 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBP | c.928G>C p.V310L | Missense Mutation (SNP) | VAF 24/300 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.105); called by muse, mutect2
- TCF7L2 | c.1180G>A p.E394K (on ENST00000355995 / NM_001367943.1; = p.E371K on NM_030756.5) | Missense Mutation (SNP) | VAF 80/318 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- TENT5A | c.19T>C p.Y7H | Missense Mutation (SNP) | VAF 339/666 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, varscan2
- TNRC18 | c.3020A>C p.K1007T | Missense Mutation (SNP) | VAF 81/799 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- TNRC6A | c.1243dup p.S415Ffs*14 | Frame Shift Ins (INS) | VAF 41/315 reads (13%) | called by mutect2, pindel, varscan2
- USP28 | c.1211T>G p.L404R | Missense Mutation (SNP) | VAF 32/280 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- WDR36 | c.2238G>C p.Q746H | Missense Mutation (SNP) | VAF 41/324 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZCCHC7 | c.1158A>T p.E386D | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF428 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 149/563 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- A3GALT2 | c.942C>T p.S314= | Silent (SNP) | VAF 178/395 reads (45%) | catalogued as rs777814427; called by muse, mutect2, varscan2
- ABI3 | c.375C>T p.I125= | Silent (SNP) | VAF 147/571 reads (26%) | catalogued as rs748149316; called by muse, varscan2
- C6orf118 | c.114G>T p.L38= | Silent (SNP) | VAF 139/480 reads (29%) | called by muse, mutect2, varscan2
- CDC25A | c.702C>T p.P234= | Silent (SNP) | VAF 134/371 reads (36%) | called by muse, mutect2, varscan2
- DCDC1 | c.1704G>A p.S568= | Silent (SNP) | VAF 136/318 reads (43%) | catalogued as rs890487026; called by muse, varscan2
- DCT | c.1131C>T p.N377= | Silent (SNP) | VAF 191/520 reads (37%) | catalogued as rs776819456, COSV65468614; called by muse, mutect2, varscan2
- FAT3 | c.2298A>T p.S766= | Silent (SNP) | VAF 45/284 reads (16%) | called by muse, mutect2, varscan2
- FAT4 | c.11916A>T p.G3972= | Silent (SNP) | VAF 64/148 reads (43%) | called by muse, mutect2, varscan2
- FREM2 | c.2487A>T p.P829= | Silent (SNP) | VAF 70/569 reads (12%) | called by muse, mutect2, varscan2
- GP5 | c.870G>A p.G290= | Silent (SNP) | VAF 112/518 reads (22%) | catalogued as rs771813293; called by muse, varscan2
- GPR137 | c.561G>A p.A187= | Silent (SNP) | VAF 193/441 reads (44%) | catalogued as rs1426704752; called by muse, mutect2, varscan2
- GPR45 | c.585C>T p.Y195= | Silent (SNP) | VAF 308/560 reads (55%) | catalogued as rs767278498, COSV51524986, COSV99307234; called by muse, mutect2, varscan2
- HHIPL2 | c.351C>T p.Y117= | Silent (SNP) | VAF 218/353 reads (62%) | catalogued as rs1291388394, COSV58563595; called by muse, mutect2, varscan2
- IL9R | c.1209G>A p.Q403= | Silent (SNP) | VAF 72/902 reads (8%) | called by muse, mutect2
- IQSEC3 | c.3351T>A p.A1117= | Silent (SNP) | VAF 152/483 reads (31%) | called by muse, mutect2, varscan2
- KCNJ4 | c.1077C>T p.T359= | Silent (SNP) | VAF 116/306 reads (38%) | catalogued as rs751714566, COSV57856821; called by muse, mutect2, varscan2
- KDM4F | c.291G>A p.Q97= | Silent (SNP) | VAF 161/413 reads (39%) | called by muse, mutect2, varscan2
- KRT14 | c.123C>T p.R41= | Silent (SNP) | VAF 366/681 reads (54%) | catalogued as rs547482686; called by muse, mutect2, varscan2
- MCF2L2 | c.2316C>T p.F772= | Silent (SNP) | VAF 51/343 reads (15%) | catalogued as rs200679619, COSV61053428; called by muse, mutect2, varscan2
- MUC3A | c.8451C>T p.T2817= | Silent (SNP) | VAF 96/579 reads (17%) | catalogued as rs912845282; called by muse, mutect2, varscan2
- OCIAD1 | c.318A>G p.E106= | Silent (SNP) | VAF 86/249 reads (35%) | called by muse, mutect2, varscan2
- OR5D3P | c.120C>T p.F40= | Silent (SNP) | VAF 101/285 reads (35%) | called by muse, mutect2, varscan2
- P2RX6 | c.738C>T p.L246= | Silent (SNP) | VAF 241/293 reads (82%) | catalogued as rs1432870194, COSV60385424; called by muse, mutect2, varscan2
- PCDHA6 | c.1677C>T p.N559= | Silent (SNP) | VAF 335/624 reads (54%) | catalogued as rs576399974; called by muse, mutect2, varscan2
- PCDHB12 | c.1383C>T p.R461= | Silent (SNP) | VAF 176/597 reads (29%) | catalogued as COSV53393177; called by muse, mutect2, varscan2
- PKD2L1 | c.1587C>T p.I529= | Silent (SNP) | VAF 96/329 reads (29%) | catalogued as rs1286609913, COSV58399406; called by muse, mutect2, varscan2
- PLEKHB2 | c.810C>A p.R270= | Silent (SNP) | VAF 76/400 reads (19%) | called by muse, varscan2
- PLXNC1 | c.1464A>G p.V488= | Silent (SNP) | VAF 68/139 reads (49%) | catalogued as COSV51574261; called by muse, mutect2, varscan2
- RBM19 | c.1422C>T p.H474= | Silent (SNP) | VAF 70/221 reads (32%) | catalogued as rs745398765; called by muse, mutect2, varscan2
- RTKN2 | c.1459C>T p.L487= | Silent (SNP) | VAF 201/356 reads (56%) | called by muse, mutect2, varscan2
- RYR2 | c.5529G>A p.L1843= | Silent (SNP) | VAF 45/544 reads (8%) | catalogued as COSV99053547; called by muse, mutect2
- SAMD4A | c.1410G>C p.G470= | Silent (SNP) | VAF 305/734 reads (42%) | catalogued as rs747712759, COSV51885334; called by muse, mutect2, varscan2
- SCAF1 | c.978C>A p.P326= | Silent (SNP) | VAF 67/543 reads (12%) | called by muse, mutect2, varscan2
- SCN10A | c.5136C>T p.I1712= | Silent (SNP) | VAF 175/448 reads (39%) | catalogued as rs757792173, COSV71860724, COSV71862422; called by muse, mutect2, varscan2
- SIRT5 | c.801G>A p.R267= | Silent (SNP) | VAF 122/362 reads (34%) | called by muse, varscan2
- SLA | c.72C>T p.S24= (on ENST00000338087 / NM_001045556.3; = p.S64= on NM_006748.4) | Silent (SNP) | VAF 91/628 reads (14%) | catalogued as rs537553065, COSV55090372; called by muse, mutect2, varscan2
- SULT2A1 | c.645C>G p.L215= | Silent (SNP) | VAF 46/469 reads (10%) | called by muse, mutect2
- SYNDIG1 | c.534G>A p.P178= | Silent (SNP) | VAF 219/778 reads (28%) | catalogued as rs536225349, COSV100965456, COSV65233168; called by muse, mutect2, varscan2
- TBC1D10B | c.93G>T p.G31= | Silent (SNP) | VAF 378/789 reads (48%) | called by muse, mutect2, varscan2
- TEAD3 | c.582G>A p.P194= | Silent (SNP) | VAF 187/386 reads (48%) | catalogued as rs758203896; called by muse, mutect2, varscan2
- TECTA | c.4878C>T p.N1626= | Silent (SNP) | VAF 165/394 reads (42%) | catalogued as rs151056317; called by muse, mutect2, varscan2
- TMEM94 | c.1644G>A p.V548= | Silent (SNP) | VAF 105/396 reads (27%) | called by muse, mutect2, varscan2
- TTN | c.63718C>A p.R21240= (on ENST00000591111; = p.R13816= on NM_003319.4) | Silent (SNP) | VAF 123/466 reads (26%) | catalogued as COSV100620224; called by muse, mutect2, varscan2
- WRN | c.2403C>T p.S801= | Silent (SNP) | VAF 17/169 reads (10%) | called by muse, mutect2, varscan2
- WWC1 | c.2940C>T p.R980= | Silent (SNP) | VAF 38/284 reads (13%) | catalogued as rs1319451686; called by muse, varscan2
- XKR4 | c.84G>A p.S28= | Silent (SNP) | VAF 72/591 reads (12%) | catalogued as COSV59338502; called by muse, varscan2
- C2orf16 | chr2:27576146 G>A | 5'Flank (SNP) | VAF 154/290 reads (53%) | catalogued as rs538908364, COSV101284453; called by muse, mutect2, varscan2
- KCNQ1 | c.1514+5814G>C | Intron (SNP) | VAF 77/307 reads (25%) | called by muse, mutect2, varscan2
- KLHL1 | c.-307G>T | 5'UTR (SNP) | VAF 36/598 reads (6%) | called by muse, mutect2
- NUDT16L1 | c.414+326C>G | Intron (SNP) | VAF 6/136 reads (4%) | catalogued as rs1056299602; called by muse, mutect2
- PEG10 | c.*1117C>T | 3'UTR (SNP) | VAF 42/391 reads (11%) | called by muse, mutect2, varscan2
- PRSS40A | n.230C>T | RNA (SNP) | VAF 62/250 reads (25%) | catalogued as rs1397339383; called by muse, mutect2, varscan2
- REXO1L1P | n.1506G>A | RNA (SNP) | VAF 86/1750 reads (5%) | catalogued as rs1448634678; called by muse, mutect2
- SPATA13 | c.-222-25455G>A | Intron (SNP) | VAF 156/640 reads (24%) | catalogued as rs1001090536; called by muse, mutect2, varscan2
- STIP1 | chr11:64185931 T>C | 5'Flank (SNP) | VAF 55/488 reads (11%) | catalogued as rs1048285787; called by muse, mutect2, varscan2
- SYNGR1 | c.*2757C>T | 3'UTR (SNP) | VAF 57/309 reads (18%) | called by muse, mutect2, varscan2
